Somatic mutation profile of tumor specimen TCGA-F9-A8NY-01A (aliquot TCGA-F9-A8NY-01A-11D-A35Z-10) from TCGA case TCGA-F9-A8NY, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 38.6 years (14,101 days).
Specimen TCGA-F9-A8NY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b51dff51-fc1f-4507-905f-320a6a824b9e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-F9-A8NY-10A (Blood Derived Normal), aliquot TCGA-F9-A8NY-10A-01D-A35Z-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/47a619b1-6b49-485c-8112-ca12574d4269

The open-access MAF lists 48 somatic variants for this specimen: 33 protein-altering or splice-affecting, 13 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Silent 13, Nonsense Mutation 4, Frame Shift Del 2, 3'Flank 1, Frame Shift Ins 1, Intron 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABRAXAS2 | c.1055C>T p.P352L | Missense Mutation (SNP) | VAF 42/165 reads (25%) | SIFT tolerated (0.6); PolyPhen benign (0.049); catalogued as COSV100044867, COSV100045016; called by muse, mutect2, varscan2
- ATG2B | c.6113C>G p.A2038G | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.755); catalogued as COSV99952115; called by muse, mutect2, varscan2
- BPIFB3 | c.268G>A p.E90K | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.02); catalogued as rs1438069274, COSV100972450, COSV64956852; called by muse, mutect2, varscan2
- CAND1 | c.79A>G p.T27A | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.059); catalogued as COSV101604402; called by muse, mutect2, varscan2
- CBLB | c.926C>A p.T309N | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51431893; called by muse, mutect2, varscan2
- CDC5L | c.7C>T p.R3* | Nonsense Mutation (SNP) | VAF 9/41 reads (22%) | catalogued as COSV101015084; called by muse, mutect2, varscan2
- CDR2L | c.362G>A p.R121H | Missense Mutation (SNP) | VAF 29/130 reads (22%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.459); catalogued as rs139957978; called by muse, mutect2, varscan2
- CNOT4 | c.748A>G p.N250D | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as COSV100211813; called by muse, mutect2, varscan2
- DDX31 | c.130A>T p.S44C | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV100140183; called by muse, mutect2, varscan2
- FRMD5 | c.1694G>C p.S565T | Missense Mutation (SNP) | VAF 38/98 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0.073); catalogued as COSV101296617; called by muse, mutect2, varscan2
- HECTD4 | c.12803T>C p.I4268T | Missense Mutation (SNP) | VAF 5/82 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV101107881; called by muse, mutect2
- IPO4 | c.1526C>T p.T509M | Missense Mutation (SNP) | VAF 39/122 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.067); catalogued as rs768075624, COSV99938126; called by muse, mutect2, varscan2
- KCNC4 | c.1813C>T p.R605W | Missense Mutation (SNP) | VAF 34/71 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.551); catalogued as rs200184574, COSV100873564; called by muse, mutect2, varscan2
- KRT27 | c.941T>A p.L314H | Missense Mutation (SNP) | VAF 33/167 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100053294; called by muse, mutect2, varscan2
- LAMB4 | c.1072G>A p.V358M | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.566); catalogued as COSV52729013; called by muse, mutect2, varscan2
- MAN2C1 | c.1236G>A p.W412* | Nonsense Mutation (SNP) | VAF 32/75 reads (43%) | catalogued as COSV99145508; called by muse, mutect2, varscan2
- MAP3K4 | c.3126T>G p.F1042L | Missense Mutation (SNP) | VAF 6/138 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as COSV100815494; called by muse, mutect2
- MATN3 | c.194C>G p.T65S | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101337451; called by muse, mutect2, varscan2
- MCF2L | c.472G>A p.A158T (on ENST00000375608; = p.A126T on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); catalogued as COSV65052423; called by muse, mutect2
- NRK | c.2215G>C p.E739Q | Missense Mutation (SNP) | VAF 112/366 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99688285; called by muse, mutect2, varscan2
- PCDHGA5 | c.1783G>A p.D595N | Missense Mutation (SNP) | VAF 34/97 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99541265; called by muse, mutect2, varscan2
- PGAM4 | c.98C>T p.A33V | Missense Mutation (SNP) | VAF 49/146 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs1197116516, COSV100431157; called by muse, mutect2, varscan2
- PHLDA1 | c.916C>T p.Q306* | Nonsense Mutation (SNP) | VAF 10/35 reads (29%) | catalogued as COSV99876662; called by muse, mutect2, varscan2
- PTCD3 | c.593A>G p.Y198C | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs200261667, COSV54480222; called by muse, mutect2, varscan2
- TG | c.1750G>T p.A584S | Missense Mutation (SNP) | VAF 40/157 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.475); catalogued as COSV99601696; called by muse, mutect2, varscan2
- TLE6 | c.544C>T p.Q182* (on ENST00000246112 / NM_001143986.2; = p.Q59* on NM_024760.3) | Nonsense Mutation (SNP) | VAF 13/40 reads (33%) | catalogued as COSV99858313; called by muse, mutect2, varscan2
- TRIML2 | c.553C>T p.R185C | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs769283563, COSV58715562; called by muse, mutect2, varscan2
- UBA3 | c.505A>G p.I169V | Missense Mutation (SNP) | VAF 67/203 reads (33%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as rs368942872; called by muse, mutect2, varscan2
- ARHGAP29 | c.874_883del p.P292Efs*13 | Frame Shift Del (DEL) | VAF 10/78 reads (13%) | called by mutect2, pindel, varscan2
- ATP2B3 | c.2917_2919del p.F973del | In Frame Del (DEL) | VAF 44/119 reads (37%) | called by mutect2, pindel, varscan2
- BICC1 | c.2186_2187dup p.D730Lfs*9 | Frame Shift Ins (INS) | VAF 34/188 reads (18%) | called by mutect2, pindel, varscan2
- IVNS1ABP | c.1685_1688del p.F562Yfs*26 | Frame Shift Del (DEL) | VAF 26/94 reads (28%) | called by mutect2, pindel, varscan2
- SYNE1 | c.25858C>A p.L8620M (on ENST00000367255 / NM_182961.4; = p.L8572M on NM_033071.3) | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CCT8L2 | c.900C>T p.D300= | Silent (SNP) | VAF 38/73 reads (52%) | catalogued as rs772533950, COSV63462162; called by muse, mutect2, varscan2
- CRYBG3 | c.6933C>T p.V2311= | Silent (SNP) | VAF 36/83 reads (43%) | catalogued as COSV99477136; called by muse, mutect2, varscan2
- DNPH1 | c.297G>A p.L99= | Silent (SNP) | VAF 15/39 reads (38%) | catalogued as COSV52733945; called by muse, mutect2, varscan2
- ELOF1 | c.129C>T p.R43= | Silent (SNP) | VAF 43/114 reads (38%) | catalogued as rs775440532, COSV99370681; called by muse, mutect2, varscan2
- FAM178B | c.1764G>A p.E588= (on ENST00000490605 / NM_001122646.3; = p.E28= on NM_016490.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as COSV100014301; called by muse, mutect2, varscan2
- FLVCR2 | c.1449C>T p.L483= | Silent (SNP) | VAF 19/74 reads (26%) | catalogued as rs1399297143, COSV99471373, COSV99471404; called by muse, mutect2, varscan2
- GRHL1 | c.1140A>G p.T380= | Silent (SNP) | VAF 27/106 reads (25%) | catalogued as COSV100257970; called by muse, mutect2, varscan2
- KLHL34 | c.1785C>T p.Y595= | Silent (SNP) | VAF 91/220 reads (41%) | catalogued as COSV101069952; called by muse, mutect2, varscan2
- NCDN | c.1584C>T p.L528= | Silent (SNP) | VAF 22/50 reads (44%) | catalogued as rs772058400, COSV100621995; called by muse, mutect2, varscan2
- PNPLA7 | c.3705C>A p.S1235= | Silent (SNP) | VAF 13/34 reads (38%) | catalogued as COSV99481002; called by muse, mutect2, varscan2
- PPP1R9A | c.978T>G p.A326= | Silent (SNP) | VAF 54/180 reads (30%) | catalogued as COSV99196250; called by muse, mutect2, varscan2
- SRSF8 | c.93G>A p.R31= | Silent (SNP) | VAF 63/159 reads (40%) | catalogued as COSV101475807; called by muse, mutect2, varscan2
- TRAPPC9 | c.3294C>A p.G1098= | Silent (SNP) | VAF 22/106 reads (21%) | catalogued as COSV101227895; called by muse, mutect2, varscan2
- MTRNR2L6 | chr7:142671051 A>C | 3'Flank (SNP) | VAF 14/54 reads (26%) | called by muse, mutect2, varscan2
- RPGR | c.2520+646G>T | Intron (SNP) | VAF 5/41 reads (12%) | called by muse, varscan2
